Gene-level copy-number profile of tumor specimen C3N-01077-03 from CPTAC case C3N-01077, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Tumor grade: G3.
Specimen C3N-01077-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cb0a1ab8-933b-46c0-b6eb-97e72efee4f3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01077-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/5ec1294d-045b-46da-9695-175696c824a5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 15,551; copy number 2: 37,160; copy number 3: 3,300; copy number 4: 2,897; copy number 5: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:101,961,603–101,979,093, 3 genes, copy number 5: WASH3P, MIR6859-3, DDX11L9.

Autosomal genes at a single copy (total copy number 1): 12,843. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
